Somatic mutation profile of tumor specimen C3N-01267-03 (aliquot CPT0027970009) from CPTAC case C3N-01267, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 57.2 years (20,897 days).
Specimen C3N-01267-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a504da77-29c8-4c94-8341-6df2c73e1a98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01267-71 (Blood Derived Normal), aliquot CPT0028110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/439d9cdc-c846-4ffa-8fc2-8ccb610d9f84

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 76/435 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- NOTCH2 | c.6909dup p.I2304Hfs*9 | Frame Shift Ins (INS) | VAF 12/82 reads (15%) | catalogued as rs771237928; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.81T>G p.Y27* | Nonsense Mutation (SNP) | VAF 91/149 reads (61%) | hotspot (GDC flag); catalogued as CM128488, COSV64291164, COSV64310374; called by muse, mutect2, varscan2
- BTNL9 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs1011434956; called by muse, mutect2, varscan2
- C2CD5 | c.1495A>G p.I499V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1007799490; called by muse, mutect2, varscan2
- GCK | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 64/361 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1306714325, CM1212981, COSV99789933; called by muse, mutect2, varscan2
- INPPL1 | c.2394G>T p.W798C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99996279; called by muse, mutect2, varscan2
- MGA | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 22/365 reads (6%) | catalogued as rs1225212904, COSV54950572, COSV54952145; called by muse, mutect2
- OBSCN | c.4559G>A p.R1520Q | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.489); catalogued as rs377740226; called by muse, mutect2
- RIN3 | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs938453022; called by muse, mutect2, varscan2
- SPOCK3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs202164599; called by muse, mutect2, varscan2
- TMEM132B | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs199976507, COSV54744376; called by muse, mutect2, varscan2
- CDC73 | c.919T>G p.F307V | Missense Mutation (SNP) | VAF 62/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNNM4 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CREBBP | c.2401T>C p.S801P | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FLNA | c.5722G>C p.A1908P (on ENST00000369850 / NM_001110556.2; = p.A1900P on NM_001456.3) | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC5B | c.13066A>G p.T4356A | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- OR2T33 | c.851A>C p.N284T | Missense Mutation (SNP) | VAF 62/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROK2 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC12A5 | c.3389G>A p.G1130D (on ENST00000454036 / NM_001134771.2; = p.G1107D on NM_020708.5) | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ZFAT | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C17orf107 | c.219G>A p.G73= | Silent (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2
- EDARADD | c.270C>A p.I90= (on ENST00000334232 / NM_145861.4; = p.I80= on NM_080738.4) | Silent (SNP) | VAF 113/305 reads (37%) | catalogued as COSV62061614; called by muse, mutect2, varscan2
- EFHC1 | c.483C>T p.D161= | Silent (SNP) | VAF 41/195 reads (21%) | catalogued as rs1184954075; called by muse, mutect2, varscan2
- H1-3 | c.51A>G p.K17= | Silent (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- IRAK3 | c.54C>T p.F18= | Silent (SNP) | VAF 51/279 reads (18%) | called by muse, mutect2, varscan2
- KCNB2 | c.867C>T p.S289= | Silent (SNP) | VAF 52/291 reads (18%) | catalogued as rs764537038, COSV101578919; called by muse, mutect2, varscan2
- MYOC | c.768G>C p.T256= | Silent (SNP) | VAF 125/277 reads (45%) | called by muse, mutect2, varscan2
- NFKBIE | c.315G>A p.G105= | Silent (SNP) | VAF 54/212 reads (25%) | called by muse, mutect2, varscan2
- SCX | c.462C>T p.R154= | Silent (SNP) | VAF 61/246 reads (25%) | called by muse, mutect2, varscan2
- GOSR2 | c.282+2985G>A | Intron (SNP) | VAF 54/201 reads (27%) | catalogued as COSV56665142; called by muse, mutect2, varscan2
- IYD | c.688-1618G>C | Intron (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
